Surgical pathology report (de-identified scan), TCGA case TCGA-F7-7848, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-7848-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED] Case ID		OC ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
[REDACTED]		[REDACTED]				

[page 2 of 2]
Formatted Path Report

LARYNX TISSUE CHECKLIST

Specimen type: Laryngectomy

Tumor site: Larynx

Tumor size: 4 x 2 cm

Histologic type: Squamous cell carcinoma, keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Deep muscles of the tongue

Lymph nodes: 1/4 positive for metastasis (Cervical 1/4)

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Comments: None

ID	Date of Procurement	Laterality

Source: NCI Genomic Data Commons file c0fe02e3-3854-4f05-821d-f289e3da886d (TCGA-F7-7848.A282C9A5-ED9F-48EC-A868-DA974A58BD3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).